Somatic mutation profile of tumor specimen 0E1KOM from CCDI case PBCWGY, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female.
Specimen 0E1KOM: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a231a835-ae7e-4e84-aa78-d6ad2064dbb6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0E1KO6 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/66a0525c-1a9e-4de5-bad2-0d6a4f281324

The open-access MAF lists 10 somatic variants for this specimen: 5 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 3, Intron 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRCA2 | c.4604C>A p.A1535E | Missense Mutation (SNP) | VAF 29/824 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.557); catalogued as rs1471265644; called by muse, mutect2
- GAS2L1 | c.1400C>T p.S467L | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.086); catalogued as rs755368144; called by muse, mutect2, varscan2
- SUPT3H | c.676G>T p.V226F (on ENST00000371460 / NM_181356.3; = p.V215F on NM_003599.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/506 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.298); catalogued as COSV100176080; called by muse, mutect2
- IL9R | c.575G>T p.W192L | Missense Mutation (SNP) | VAF 28/272 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZFP42 | c.591G>T p.R197S | Missense Mutation (SNP) | VAF 8/181 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.185); called by muse, mutect2
- CCDC168 | c.5727T>C p.G1909= | Silent (SNP) | VAF 27/323 reads (8%) | called by muse, mutect2
- CROCC | c.2151C>A p.R717= | Silent (SNP) | VAF 86/207 reads (42%) | called by muse, mutect2, varscan2
- GC | c.504A>C p.G168= | Silent (SNP) | VAF 151/341 reads (44%) | called by muse, mutect2, varscan2
- LIPF | c.422+22A>C | Intron (SNP) | VAF 78/160 reads (49%) | called by muse, mutect2, varscan2
- MUC19 | chr12:40525306 T>G | 5'Flank (SNP) | VAF 5/49 reads (10%) | called by muse, mutect2
